Somatic mutation profile of tumor specimen C3L-02899-01 (aliquot CPT0197420007) from CPTAC case C3L-02899, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 73.1 years (26,705 days).
Specimen C3L-02899-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acc38f86-81ed-40a9-95db-ae03374bd065.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02899-31 (Blood Derived Normal), aliquot CPT0199150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6266443-0a0e-4469-80e3-c5f9613b76c8

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Intron 2, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 50/416 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.920-1G>T p.X307_splice | Splice Site (SNP) | VAF 46/325 reads (14%) | hotspot (GDC flag); catalogued as rs587781702, CS0910927, CS114009, COSV52664150, COSV52690279, COSV52737535; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACR | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139648296; called by muse, mutect2
- ADAMTS4 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 44/373 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs1242506429, COSV100917463; called by muse, mutect2, varscan2
- CACNA1C | c.6469G>A p.A2157T (on ENST00000399634 / NM_001167625.1; = p.A2086T on NM_000719.7) | Missense Mutation (SNP) | VAF 42/394 reads (11%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs763324710; called by muse, mutect2, varscan2
- ICA1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs766630394; called by muse, mutect2, varscan2
- KCNH6 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 33/585 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368030494; called by muse, mutect2
- OGDHL | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1227541536, COSV100934495; called by muse, mutect2, varscan2
- PHKG1 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 70/570 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as rs763494578, COSV51914856; called by muse, mutect2, varscan2
- PPFIA4 | c.2248C>T p.R750C (on ENST00000447715; = p.R751C on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/498 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs750034692; called by muse, mutect2
- RABAC1 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 50/440 reads (11%) | catalogued as COSV55770684; called by muse, mutect2, varscan2
- TRAPPC6B | c.365C>T p.T122M (on ENST00000330149 / NM_001079537.2; = p.T94M on NM_177452.4) | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs1342382352; called by muse, mutect2, varscan2
- ACIN1 | c.2200G>T p.E734* | Nonsense Mutation (SNP) | VAF 46/329 reads (14%) | called by muse, mutect2, varscan2
- CES4A | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 61/435 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CSMD2 | c.8981G>T p.C2994F | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF5B | c.470del p.S157* | Frame Shift Del (DEL) | VAF 19/154 reads (12%) | called by mutect2, pindel, varscan2
- KANSL2 | c.1005C>G p.F335L | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LONRF3 | c.1577T>G p.L526R (on ENST00000371628 / NM_001031855.3; = p.L485R on NM_024778.5) | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR11H6 | c.950A>T p.D317V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRSS1 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 49/475 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- SLK | c.2663C>A p.T888N | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX1 | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TGFBR2 | c.1286T>A p.V429D | Missense Mutation (SNP) | VAF 53/407 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AL133500.1 | c.1650G>A p.L550= | Silent (SNP) | VAF 40/190 reads (21%) | catalogued as rs1344542630; called by muse, mutect2, varscan2
- GIPR | c.735G>A p.L245= | Silent (SNP) | VAF 66/632 reads (10%) | called by muse, mutect2, varscan2
- NUP98 | c.4407G>A p.S1469= (on ENST00000359171 / NM_001365126.1; = p.S1452= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 54/444 reads (12%) | catalogued as rs373056120; called by muse, mutect2, varscan2
- OR5K1 | c.468C>T p.S156= | Silent (SNP) | VAF 27/479 reads (6%) | called by muse, mutect2
- OSBPL1A | c.1932C>T p.L644= (on ENST00000319481 / NM_080597.4; = p.L131= on NM_018030.4) | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, varscan2
- U2AF2 | c.39G>A p.E13= | Silent (SNP) | VAF 51/382 reads (13%) | catalogued as rs1451127113; called by muse, mutect2, varscan2
- WNK2 | c.2601G>A p.A867= | Silent (SNP) | VAF 32/228 reads (14%) | catalogued as rs375757039; called by muse, mutect2, varscan2
- DST | c.4297-4067G>T | Intron (SNP) | VAF 20/389 reads (5%) | called by muse, mutect2
- WDR49 | c.487-6649C>T | Intron (SNP) | VAF 10/158 reads (6%) | catalogued as rs552286041, COSV57701463; called by muse, mutect2
